Gene-level copy-number profile of tumor specimen TCGA-30-1891-01A from TCGA case TCGA-30-1891, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 61.2 years (22,344 days).
Specimen TCGA-30-1891-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.3d12d22b-4400-4141-9ee8-111bd81681ab.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-30-1891-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/eeadf128-8ec5-4db5-8e28-a901b7365336

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 22,145; copy number 2: 29,578; copy number 3: 6,553; copy number 4: 881; copy number 5: 598; copy number 6: 24; copy number 7: 21.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-30-1891-01A-01D-0648-01): tumor purity 0.78, ploidy 1.86, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:178,685,886–178,685,956, 1 gene: AC017087.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 643 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:51,907,956–52,348,671, 18 genes, copy number 5 (within-gene range 3–5): RAB3B, RNA5SP48, AL445685.2, RN7SL290P, TXNDC12, AL445685.3, KTI12, AL445685.1, TXNDC12-AS1, BTF3L4, ZFYVE9, RN7SL788P, AL139156.2, AL139156.1, PDCL3P6, AL139156.3, DNAJC19P7, ANAPC10P1.
- chr7:156,633,355–159,233,377, 45 genes, copy number 5: AC005534.1, RNF32, RNF32-AS1, LMBR1, RNU4-31P, AC006357.1, NOM1, MNX1, MNX1-AS2, MNX1-AS1, AC006967.2, AC006967.1, AC006967.3, UBE3C, RPS27AP12, AC004898.1, AC004975.1, AC004975.2, DNAJB6, AC006372.3, AC006372.1, AC006372.2, AC006372.4, PTPRN2, MIR153-2, AC005481.1, AC006003.1, PTPRN2-AS1, AC011899.2, AC011899.3, AC011899.1, MIR595, AC078942.1, LINC01022, MIR5707, THAP5P1, NCAPG2, AC019084.1, ESYT2, DYNC2I1, AC004863.1, LINC00689, VIPR2, AC007269.1, PIP5K1P2.
- chr8:115,408,496–118,622,112, 24 genes, copy number 6 (within-gene range 4–6): TRPS1, AF178030.1, LINC00536, RNA5SP276, AC090994.1, AC105177.1, EIF3H, UTP23, RAD21, RAD21-AS1, MIR3610, AARD, SLC30A8, RN7SL228P, AC027419.1, AC027419.2, RN7SL826P, AC084114.1, AP002848.1, MED30, RPS10P16, EXT1, SAMD12, AC023590.1.
- chr8:120,913,065–121,119,754, 2 genes, copy number 5: AC068413.1, AC011626.1.
- chr8:126,474,189–141,308,305, 166 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr12:7,689,784–22,690,665, 388 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 21,380. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
